Somatic mutation profile of tumor specimen BLGSP-71-19-00118-09A (aliquot BLGSP-71-19-00118-09A-01D-A690-33) from CGCI case BLGSP-71-19-00118, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 18.7 years (6,825 days).
Specimen BLGSP-71-19-00118-09A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9aed443-8413-46e3-b3c4-152403be58ba.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00118-16A (Mononuclear Cells from Bone Marrow Normal), aliquot BLGSP-71-19-00118-16A-01D-A690-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73af9db1-5bb3-469b-8862-b2740c61960b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, In Frame Del 1, 5'UTR 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 150/166 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121912667, CM083790, COSV52676438, COSV53038615, COSV53625652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2928G>T p.L976F | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758606; called by muse, mutect2, varscan2
- BTK | c.1156T>C p.S386P | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DDX3X | c.605del p.P202Qfs*18 (on ENST00000399959; = p.P203Qfs*18 on NM_001356.5) | Frame Shift Del (DEL) | VAF 159/240 reads (66%) | called by mutect2, pindel, varscan2
- GNAI2 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 92/220 reads (42%) | called by pindel, varscan2
- SUSD2 | c.2319A>G p.S773= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- MYC | c.-57G>A | 5'UTR (SNP) | VAF 14/186 reads (8%) | catalogued as rs1341347436, COSV52369845, COSV52372136; called by muse, mutect2
